TCGA case TCGA-3T-AA9L — Thymoma (TCGA-THYM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Thymic Epithelial Neoplasms; Primary site: Thymus; Tissue source site: Emory University. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/eddb3067-a0e5-461f-a8b8-95081ec67de0

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: United States; Age at index: 31 years; Vital status: Alive.

Diagnoses (5)
1. Thymoma, type B1, malignant (the primary disease): ICD-O-3 morphology code: 8583/3; ICD-10 code: C37; Tissue or organ of origin: Thymus; Site of resection or biopsy: Anterior mediastinum; Classification of tumor: primary; Age at diagnosis: 31.8 years (11,610 days); Year of diagnosis: 2011; Method of diagnosis: Surgical Resection; Masaoka stage: Stage IIa; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,050 days (2.9 years).
   Pathology details: Consistent pathology review: Yes.
   Recorded as not given: adjuvant Ablation or Embolization, NOS; adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Thymoma, type B1, malignant), site: Thymus. Age at diagnosis: 33.7 years (12,312 days); Days to diagnosis: 702 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Recurrent Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Recurrent Disease.
3. Metastasis of diagnosis 1 (Thymoma, type B1, malignant), site: Bone, NOS. Age at diagnosis: 33.7 years (12,312 days); Days to diagnosis: 702 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease.
4. Metastasis of diagnosis 1 (Thymoma, type B1, malignant), site: Lung, NOS. Age at diagnosis: 33.7 years (12,312 days); Days to diagnosis: 702 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease.
5. Metastasis of diagnosis 1 (Thymoma, type B1, malignant), site: Lymph node, NOS. Age at diagnosis: 33.7 years (12,312 days); Days to diagnosis: 702 days (1.9 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Radiation Therapy, NOS; Initial disease status: Progressive Disease.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease.

Follow-up (6 entries)
- Days to follow up: 36 days; Disease response: Tumor Free.
- Day 702 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 702 days (1.9 years).
- Day 702 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 702 days (1.9 years).
- Day 702 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Thymus; Days to recurrence: 702 days (1.9 years).
- Day 702 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Bone, NOS; Days to progression: 702 days (1.9 years).
- Days to follow up: 1,050 days (2.9 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 86 kg; Height: 168 cm; BMI: 30.5.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3T-AA9L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-3T-AA9L-01A-01-TS1: Section location: Top; Percent tumor cells: 99; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 1; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3T-AA9L-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3T-AA9L-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free.
- Stage record: Masaoka stage: IIa.
- Primary pathology, Histological type list: Histologic diagnosis: Thymoma, Type B1.
- Primary pathology: Method initial path diagnosis: Video-assisted Thorascopic Surgery (VATS); History myasthenia gravis: No.
- Follow-up form: Lost to follow-up: No; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,050 days; disease-specific survival: no event (censored), 1,050 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 702 days.
